Somatic mutation profile of tumor specimen C3N-02590-01 (aliquot CPT0187590020) from CPTAC case C3N-02590, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.5 years (25,019 days).
Specimen C3N-02590-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b27b3524-da01-4e86-9cdb-8012a2f582cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02590-31 (Blood Derived Normal), aliquot CPT0187630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4c52a8d-9f20-41d7-a7da-4ef0f8fd9bba

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Splice Region 3, 3'UTR 2, Nonsense Mutation 2, Intron 2, Splice Site 2, RNA 1, 5'UTR 1, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 100/830 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1058A>C p.Y353S | Missense Mutation (SNP) | VAF 69/573 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 152/817 reads (19%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF7 | c.2510C>T p.A837V (on ENST00000646102 / NM_001354046.1; = p.A621V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/648 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV54542143; called by muse, mutect2
- CAPN5 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 128/1426 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs374497977; called by muse, mutect2
- GRM6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1195558693; called by muse, mutect2, varscan2
- IARS2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.076); catalogued as COSV56958476; called by muse, mutect2
- NEXMIF | c.3437C>A p.S1146Y | Missense Mutation (SNP) | VAF 88/884 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV50067061; called by muse, mutect2, varscan2
- NUP107 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs199858234; called by muse, mutect2, varscan2
- OTUD4 | c.217C>T p.R73* (on ENST00000447906 / NM_001366057.1; = p.R8* on NM_017493.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/298 reads (10%) | catalogued as COSV56849995; called by muse, mutect2, varscan2
- PRKAB1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 75/752 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319163692; called by muse, mutect2, varscan2
- SARDH | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 139/1325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1471841676, COSV64100100; called by muse, mutect2, varscan2
- ZNF41 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57442573; called by muse, mutect2, varscan2
- CACNA1S | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 96/1229 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CELSR3 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 75/723 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTAG2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 142/1092 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ESCO1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 151/490 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 115/984 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HDAC8 | c.1005G>A p.E335= | Splice Region (SNP) | VAF 58/357 reads (16%) | called by muse, mutect2, varscan2
- HKDC1 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- HUWE1 | c.646-7A>G | Splice Region (SNP) | VAF 37/359 reads (10%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- LLGL2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIB1 | c.2586+5_2586+15del p.X862_splice | Splice Site (DEL) | VAF 30/223 reads (13%) | called by mutect2, pindel, varscan2
- MTA1 | c.1935del p.R646Gfs*3 | Frame Shift Del (DEL) | VAF 54/566 reads (10%) | called by mutect2, pindel
- NT5C | c.466_467dup p.S157Qfs*36 | Frame Shift Ins (INS) | VAF 99/546 reads (18%) | called by mutect2, pindel, varscan2
- P2RX2 | c.1115T>C p.L372S | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2
- PARP4 | c.3288A>T p.A1096= | Splice Region (SNP) | VAF 54/446 reads (12%) | called by muse, mutect2, varscan2
- PPEF2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 77/793 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.3965T>C p.I1322T | Missense Mutation (SNP) | VAF 117/889 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERINC4 | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 162/1773 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- TAMALIN | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 60/574 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ACOT12 | c.1527C>T p.Y509= | Silent (SNP) | VAF 17/359 reads (5%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1440G>A p.V480= | Silent (SNP) | VAF 49/460 reads (11%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8529C>T p.L2843= (on ENST00000357337; = p.L2881= on NM_015057.5) | Silent (SNP) | VAF 28/649 reads (4%) | catalogued as rs754283675; called by muse, mutect2
- NXPE1 | c.214A>C p.R72= | Silent (SNP) | VAF 34/1081 reads (3%) | called by muse, mutect2
- PALB2 | c.828C>T p.H276= | Silent (SNP) | VAF 115/1251 reads (9%) | catalogued as rs911713488, COSV55166306; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- RFX1 | c.2478C>T p.D826= | Silent (SNP) | VAF 120/1001 reads (12%) | catalogued as rs1200947508; called by muse, mutect2, varscan2
- SALL3 | c.2454G>A p.P818= | Silent (SNP) | VAF 37/343 reads (11%) | catalogued as rs1252378463; called by muse, mutect2, varscan2
- AL136982.4 | n.218G>T | RNA (SNP) | VAF 43/1409 reads (3%) | called by muse, mutect2
- DOT1L | c.4606+672G>A | Intron (SNP) | VAF 187/1818 reads (10%) | called by muse, mutect2, varscan2
- IMPDH1 | c.*7C>T | 3'UTR (SNP) | VAF 94/602 reads (16%) | catalogued as rs375608202; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442398 G>A | 3'Flank (SNP) | VAF 24/217 reads (11%) | catalogued as rs762382967; called by muse, mutect2
- RGS3 | c.2038-18099G>A | Intron (SNP) | VAF 41/519 reads (8%) | called by muse, mutect2
- TESC | c.-103C>A | 5'UTR (SNP) | VAF 40/289 reads (14%) | called by muse, mutect2, varscan2
- UVSSA | c.*9522G>A | 3'UTR (SNP) | VAF 252/2334 reads (11%) | catalogued as rs765989288, COSV61351352; called by muse, varscan2
